TARGET case TARGET-30-PAIXBP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/0b072632-2b6f-5080-9552-b03ee7cb1715

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 2.3 years (832 days); Year of diagnosis: 2000; Days to last follow up: 1,073 days (2.9 years); INSS stage: Stage 4.
